MMRF case MMRF_1944 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/17c2388c-de15-4ad9-9a3c-83a8574f9578

Demographics
Sex at birth: female; Ethnicity: not hispanic or latino; Age at index: 66 years; Vital status: Dead; Days to death: 96 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 66.7 years (24,352 days); ISS stage: III; Days to last known disease status: 96 days; Days to last follow up: 96 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 49 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 4 days; Days to treatment end: 84 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 4 days; Days to treatment end: 19 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 33 days; Days to treatment end: 40 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 67 days; Days to treatment end: 84 days.

Follow-up (2 entries)
- Days to follow up: 1 day; ECOG performance status: 2.
- Follow-up contact recording only the day: day 96.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- Calcium 2.25 mmol/L.
- Albumin 34 g/L.
- Serum Free Immunoglobulin Light Chain, Kappa 2.6 mg/dL.
- Immunoglobulin G 4.21 g/L.
- Beta 2 Microglobulin 15.3 µg/mL.
- M Protein 0.18 g/dL.
- Immunoglobulin M 0.08 g/L.
- Hemoglobin 5.89 mmol/L.
- Absolute Neutrophil 2.9 ×10⁹/L.
- Glucose 7.43 mmol/L.
- Creatinine 265 µmol/L.
- Serum Free Immunoglobulin Light Chain, Lambda 257 mg/dL.
- Total Protein 5.7 g/dL.
- Platelets 199 ×10⁹/L.
- Immunoglobulin A 0.09 g/L.
- Blood Urea Nitrogen 17.5 mmol/L.
- Leukocytes 4 ×10⁹/L.
- C-Reactive Protein 0.5 mg/dL.

Other clinical attributes
- Day 1: Weight: 45 kg; Height: 150 cm.

Biospecimens (2 samples)
- Sample MMRF_1944_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1944_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
